Gene-level copy-number profile of tumor specimen TCGA-50-5066-01A from TCGA case TCGA-50-5066, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.2 years (26,385 days).
Specimen TCGA-50-5066-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f78feb9a-4ab0-465a-8c5d-e3a75cb1d53e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-5066-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a08e931b-cc9f-4e26-a9ed-520c663fc244

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 535; copy number 2: 11,306; copy number 3: 19,557; copy number 4: 19,407; copy number 5: 5,356; copy number 6: 1,832; copy number 7: 352; copy number 8: 751; copy number 9: 14; copy number 10: 265; copy number 11: 244; copy number 12: 95; copy number 16: 11; copy number 17: 32; copy number 19: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5066-01A-01D-1624-01): tumor purity 0.27, ploidy 2.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,821 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–156,007,070, 583 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr1:162,541,332–164,357,364, 25 genes, copy number 7: UQCRBP2, AL596325.1, UAP1, AL596325.2, DDR2, RN7SL861P, HSD17B7, CCDC190, AL392003.2, AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6.
- chr5:58,198–17,670,571, 340 genes, copy number 7–19 (broad region; genes not listed).
- chr7:70,972–9,189,857, 208 genes, copy number 10 (broad region; genes not listed).
- chr7:106,035,798–117,323,152, 153 genes, copy number 8–17 (broad region; genes not listed).
- chr7:117,332,761–117,440,780, 3 genes, copy number 17: AC002465.1, ASZ1, ANKRD49P4.
- chr8:32,647,202–32,647,390, 1 gene, copy number 8: AC083977.1.
- chr8:41,261,962–43,030,535, 52 genes, copy number 12 (within-gene range 5–12): SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA.
- chr8:46,697,630–48,824,062, 54 genes, copy number 12–16: ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1.
- chr8:88,032,011–98,294,393, 160 genes, copy number 7 (broad region; genes not listed).
- chr12:32,399,529–32,646,050, 1 gene, copy number 7 (within-gene range 5–7): FGD4.
- chr12:32,679,200–34,249,958, 32 genes, copy number 7: DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr19:28,883,430–33,064,888, 81 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr19:35,825,372–36,777,078, 54 genes, copy number 11 (within-gene range 6–11): NPHS1, KIRREL2, APLP1, RN7SL402P, NFKBID, AD000864.1, HCST, TYROBP, LRFN3, AF038458.3, AF038458.1, AF038458.2, SDHAF1, SYNE4, AC002116.1, ALKBH6, AC002116.2, CLIP3, THAP8, WDR62, AD000813.1, OVOL3, POLR2I, TBCB, AD001527.2, CAPNS1, AD001527.1, COX7A1, AC002984.1, ZNF565, Y_RNA, ZNF146, LINC00665, AC092296.2, ZFP14, AC092296.1, AC092296.4, ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2.
- chr21:21,933,315–22,154,299, 5 genes, copy number 11: AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1.
- chr21:22,882,582–23,490,724, 12 genes, copy number 10: AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1.
- chr21:30,089,717–30,396,822, 14 genes, copy number 9: AF096876.1, CLDN17, LINC00307, CLDN8, RPL8P2, KRTAP24-1, KRTAP25-1, KRTAP26-1, KRTAP27-1, KRTAP23-1, KRTAP13-6P, KRTAP13-2, MIR4327, KRTAP13-1.
- chr21:38,380,027–39,929,397, 43 genes, copy number 8 (within-gene range 3–8): ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001042.3, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.3, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1, BRWD1, AF129408.1, TIMM9P2, BRWD1-IT1, METTL21AP1, BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA, RNF6P1, GET1, GET1-SH3BGR, LCA5L, SH3BGR, MIR6508, MYL6P2, RPS26P4, JCADP1, B3GALT5, B3GALT5-AS1, AF064860.1, AF064860.2, IGSF5, PCP4.

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
